Somatic mutation profile of tumor specimen 927f0958-db5a-4bc5-92b7-2a3695 (aliquot 927f0958-db5a-4bc5-92b7-2a3695_D6) from CPTAC case 02OV040, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 927f0958-db5a-4bc5-92b7-2a3695: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 569f734c-6e30-4604-8dbb-df50a054880a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 93b7f944-b465-4778-9c86-106f96 (Blood Derived Normal), aliquot 93b7f944-b465-4778-9c86-106f96_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d077f458-3f9e-4d9a-ae9b-f994db672382

The open-access MAF lists 89 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 16, Intron 8, Nonsense Mutation 4, Frame Shift Del 3, 3'UTR 2, In Frame Del 1, 3'Flank 1, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM107 | c.*671G>A | 3'UTR (SNP) | VAF 10/65 reads (15%) | catalogued as rs886039784; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.737T>G p.M246R | Missense Mutation (SNP) | VAF 120/292 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780074, CM157012, COSV52668375, COSV52693504, COSV52778210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774299788, COSV55958979; called by muse, mutect2, varscan2
- AMER1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs147754688, COSV100366837; called by muse, mutect2, varscan2
- AMMECR1L | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.14); catalogued as rs1246056513, COSV55762332; called by muse, mutect2, varscan2
- BCL9 | c.2515C>G p.R839G | Missense Mutation (SNP) | VAF 39/680 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.551); catalogued as COSV52351193; called by muse, mutect2
- CAMTA1 | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113652510, COSV100349428; called by muse, mutect2, varscan2
- CDC42BPA | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV62009001; called by muse, mutect2, varscan2
- CNGB3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 67/619 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs369083450; called by muse, mutect2, varscan2
- DDX46 | c.1652G>C p.R551P | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62798529; called by muse, mutect2, varscan2
- DENND2B | c.2820del p.I940Mfs*20 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV58204564; called by mutect2, pindel, varscan2
- EPHB1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 124/241 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373140258, COSV67661504; called by muse, mutect2, varscan2
- FAP | c.2227C>A p.H743N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1449218312; called by muse, mutect2, varscan2
- HECTD4 | c.8621A>G p.N2874S | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.937); catalogued as rs1431420616; called by muse, mutect2, varscan2
- LDLRAD4 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs371089156; called by muse, mutect2, varscan2
- LIMK2 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 106/222 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs946129705; called by muse, varscan2
- OXLD1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.637); catalogued as COSV100235695; called by muse, mutect2, varscan2
- PICK1 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 105/476 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1306797006; called by mutect2, varscan2
- PLSCR3 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs934602838; called by muse, mutect2, varscan2
- POLR1G | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs762618583; called by muse, mutect2, varscan2
- SIN3B | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 30/501 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as rs1424591317; called by muse, mutect2
- TMEM74 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748151015, COSV52462954; called by muse, mutect2, varscan2
- TNC | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | catalogued as rs867695219, COSV60784297; called by muse, mutect2
- UBXN1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs761509176, COSV53657417, COSV53657652; called by muse, mutect2, varscan2
- ABCA2 | c.38del p.P13Lfs*69 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- ABCA9 | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2
- AK5 | c.195G>T p.K65N (on ENST00000354567 / NM_174858.3; = p.K39N on NM_012093.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- ALPP | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.063); called by muse, varscan2
- ARHGAP11B | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ARHGEF28 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CAGE1 | c.1156G>T p.E386* (on ENST00000512086; = p.E250* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 98/209 reads (47%) | called by muse, mutect2, varscan2
- CALML6 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2
- CCDC69 | c.671A>C p.E224A | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CPB1 | c.359del p.N120Tfs*6 | Frame Shift Del (DEL) | VAF 107/241 reads (44%) | called by mutect2, pindel, varscan2
- DNALI1 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- ENPEP | c.721G>C p.A241P | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- F2R | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 122/503 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by mutect2, varscan2
- FAM117A | c.480A>C p.Q160H | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- FAM71E1 | c.484G>C p.D162H (on ENST00000600100 / NM_001308429.2; = p.D146H on NM_138411.3) | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FRAS1 | c.4072C>T p.P1358S | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- GTF2I | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2
- JDP2 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MINK1 | c.1871C>G p.P624R | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MYO5A | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 68/544 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR11G2 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OTULIN | c.1008C>A p.D336E | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKD1L1 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.477); called by muse, mutect2
- POTEI | c.1062C>A p.C354* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- POU5F1B | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 117/1550 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRKAR2B | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); called by muse, mutect2
- RNF175 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCYL1 | c.923T>G p.F308C | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2
- SP9 | c.1210A>C p.S404R | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRGAP3 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 70/362 reads (19%) | called by muse, mutect2, varscan2
- STK16 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SVIL | c.787T>C p.S263P | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX14 | c.1338G>T p.M446I (on ENST00000240361 / NM_001201457.2; = p.M440I on NM_031272.5) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TEX38 | c.138_143del p.E46_A48delinsD | In Frame Del (DEL) | VAF 26/276 reads (9%) | called by mutect2, pindel
- TIMELESS | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- ZMIZ2 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHR | c.1734G>A p.T578= | Silent (SNP) | VAF 43/295 reads (15%) | catalogued as rs200030191, COSV54125278; called by muse, mutect2, varscan2
- CHRNA2 | c.501C>T p.S167= | Silent (SNP) | VAF 18/380 reads (5%) | catalogued as rs1175097272; called by muse, mutect2
- DHX34 | c.423G>A p.L141= | Silent (SNP) | VAF 128/298 reads (43%) | called by muse, mutect2, varscan2
- INSM1 | c.837G>T p.P279= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- MUC6 | c.2928G>A p.L976= | Silent (SNP) | VAF 78/355 reads (22%) | catalogued as COSV70145374; called by mutect2, varscan2
- MVK | c.519C>T p.C173= | Silent (SNP) | VAF 107/798 reads (13%) | catalogued as rs554487221, COSV57331849; ClinVar: likely benign; called by muse, mutect2, varscan2
- MVP | c.1354C>A p.R452= | Silent (SNP) | VAF 51/377 reads (14%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1281G>A p.T427= | Silent (SNP) | VAF 118/333 reads (35%) | catalogued as rs376665704; called by muse, mutect2, varscan2
- PCDH18 | c.2556C>T p.N852= | Silent (SNP) | VAF 31/102 reads (30%) | called by muse, mutect2, varscan2
- PRRT4 | c.996C>T p.R332= | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as rs1193124234; called by muse, mutect2
- RBMXL3 | c.2922C>T p.S974= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs781892590, COSV57759581; called by muse, mutect2, varscan2
- SENP7 | c.411G>A p.S137= | Silent (SNP) | VAF 34/199 reads (17%) | catalogued as rs368202213, COSV58614042; called by muse, mutect2, varscan2
- SYNE1 | c.18610C>T p.L6204= (on ENST00000367255 / NM_182961.4; = p.L6133= on NM_033071.3) | Silent (SNP) | VAF 206/558 reads (37%) | called by muse, mutect2, varscan2
- TMEM132D | c.1698C>T p.R566= | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as rs757029767, COSV67160902; called by muse, mutect2, varscan2
- TYW1B | c.747C>G p.S249= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- ZBTB48 | c.621C>T p.P207= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs1332360836; called by muse, mutect2, varscan2
- ARHGAP5 | c.-228C>G | 5'UTR (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- C19orf54 | c.392+10C>T | Intron (SNP) | VAF 9/185 reads (5%) | catalogued as rs1202427353; called by muse, mutect2
- CLEC16A | c.2807-4158C>T | Intron (SNP) | VAF 39/220 reads (18%) | catalogued as rs1490136805; called by muse, mutect2, varscan2
- CSMD3 | c.9863-33C>G | Intron (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- DAW1 | c.973+5147G>A | Intron (SNP) | VAF 18/373 reads (5%) | catalogued as rs1040481236; called by muse, mutect2
- EIF2B1 | c.483-17C>T | Intron (SNP) | VAF 12/179 reads (7%) | called by muse, mutect2
- GUCY2EP | n.1729G>T | RNA (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- KIZ | chr20:21126051 T>C | 5'Flank (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- LMNA | c.*22G>C | 3'UTR (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- NRG1 | c.701-4789G>A | Intron (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- TINF2 | c.1062-16C>T | Intron (SNP) | VAF 52/1001 reads (5%) | called by muse, mutect2
- TPM2 | chr9:35682795 C>T | 3'Flank (SNP) | VAF 37/242 reads (15%) | catalogued as rs1418480015; called by muse, mutect2, varscan2
- VIM | c.563+42del | Intron (DEL) | VAF 20/122 reads (16%) | catalogued as rs1425569717; called by pindel, varscan2
